Gene-level copy-number profile of tumor specimen TCGA-F7-A50I-01A from TCGA case TCGA-F7-A50I, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 72.2 years (26,373 days).
Specimen TCGA-F7-A50I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.1ed05f46-8805-4a35-a745-6bfcf1c8d95a.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,842 have no estimate.
https://portal.gdc.cancer.gov/files/db58e5b3-4042-41dd-ae26-44592c57374e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 184; copy number 2: 9,344; copy number 3: 12,206; copy number 4: 18,808; copy number 5: 6,231; copy number 6: 5,817; copy number 7: 4,191.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F7-A50I-01A-11D-A28Q-01): tumor purity 0.26, ploidy 3.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 184. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
